MMRF case MMRF_1300 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/23a54468-f08a-4c2c-b299-c97bc1cbeaff

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.2 years (22,705 days); Days to last known disease status: 1,460 days (4.0 years); Days to last follow up: 1,460 days (4.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 154 days; Days to treatment end: 207 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 207 days; Days to treatment end: 490 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 490 days (1.3 years); Days to treatment end: 727 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 910 days (2.5 years); Days to treatment end: 1,479 days (4.0 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,484 days (4.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,492 days (4.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,460.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3440 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.304 mg/dL; Immunoglobulin G 32.7 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.01 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 3.25 mmol/L; Albumin 37 g/L; Total Protein 9.6 g/dL; Glucose 4.9 mmol/L.
- Day 139 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 977 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 27.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.01 mmol/L.
- Day 200 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.372 mg/dL; Immunoglobulin G 6.17 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 29.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 269 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.677 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 22.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 328 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 15.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.654 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 454: M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.626 mg/dL; Immunoglobulin G 17.3 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 23.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.68 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 4.95 mmol/L.
- Day 544: M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.829 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 30.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.24 mmol/L.
- Day 615 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.795 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.832 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 30.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.68 mmol/L.
- Day 727 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.785 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.799 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 5.5 mmol/L.
- Day 790: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.952 mg/dL; Immunoglobulin G 9.19 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 37.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 874 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 963 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.63 mmol/L; Albumin 37 g/L; Total Protein 7.4 g/dL; Glucose 4.9 mmol/L.
- Day 1,070 (ECOG 1): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 51.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.889 mg/dL; Immunoglobulin G 29.6 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 362 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.83 mmol/L; Albumin 33 g/L; Total Protein 8.5 g/dL; Glucose 4.95 mmol/L.
- Day 1,285 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,397 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.693 mg/dL; Immunoglobulin G 26 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.63 mmol/L; Albumin 30 g/L; Total Protein 8 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -10: Weight: 51 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1300_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1300_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
